Somatic mutation profile of tumor specimen TCGA-56-8201-01A (aliquot TCGA-56-8201-01A-11D-2244-08) from TCGA case TCGA-56-8201, project TCGA-LUSC (Lung Squamous Cell Carcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Upper lobe, lung; AJCC pathologic stage: Stage IIB; Age at diagnosis: 74.5 years (27,211 days).
Specimen TCGA-56-8201-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 6c15f7de-403b-4135-b34a-0d6b3df64109.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-56-8201-10A (Blood Derived Normal), aliquot TCGA-56-8201-10A-01D-2244-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/805aaa05-f29f-4d89-9a48-35e93a35ec7f

The open-access MAF lists 171 somatic variants for this specimen: 134 protein-altering or splice-affecting, 37 silent.
By variant classification: Missense Mutation 119, Silent 37, Nonsense Mutation 5, Splice Site 5, Frame Shift Del 5.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- DTD2 | c.16C>T p.R6W | Missense Mutation (SNP) | VAF 6/35 reads (17%) | hotspot (GDC flag); SIFT deleterious (0.02); PolyPhen benign (0.425); catalogued as rs17097904; called by muse, mutect2
- TP53 | c.524G>A p.R175H | Missense Mutation (SNP) | VAF 83/217 reads (38%) | hotspot (GDC flag); SIFT tolerated (0.11); PolyPhen benign (0.319); catalogued as rs28934578, CM062017, CM951224, COSV52661038, COSV52677601, COSV52731306, COSV53801286; ClinVar: pathogenic / likely pathogenic / not provided; called by muse, mutect2, varscan2
- ABCG5 | c.1729G>A p.V577I | Missense Mutation (SNP) | VAF 13/35 reads (37%) | SIFT tolerated (0.16); PolyPhen benign (0.323); catalogued as COSV99570918; called by muse, mutect2, varscan2
- ADAM12 | c.1082A>G p.D361G | Missense Mutation (SNP) | VAF 29/116 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100900107, COSV64103821; called by muse, mutect2, varscan2
- AGAP2 | c.1228-2A>G p.X410_splice (on ENST00000547588 / NM_001122772.2; = p.X74_splice on NM_014770.4) | Splice Site (SNP) | VAF 39/208 reads (19%) | catalogued as COSV57733101; called by muse, mutect2, varscan2
- AHCTF1 | c.2318A>G p.K773R (on ENST00000366508; = p.K747R on NM_015446.5) | Missense Mutation (SNP) | VAF 4/57 reads (7%) | SIFT tolerated (0.14); PolyPhen benign (0.021); catalogued as COSV100403210; called by muse, mutect2
- AL031777.2 | c.146C>T p.P49L | Missense Mutation (SNP) | VAF 26/126 reads (21%) | SIFT deleterious, low confidence (0.05); PolyPhen probably damaging (0.961); catalogued as rs763494296, COSV61911881; called by muse, mutect2, varscan2
- ALKBH3 | c.701G>T p.R234I | Missense Mutation (SNP) | VAF 15/90 reads (17%) | SIFT deleterious (0.04); PolyPhen benign (0.069); catalogued as COSV100236098; called by muse, mutect2, varscan2
- AP3D1 | c.1411A>G p.S471G | Missense Mutation (SNP) | VAF 37/140 reads (26%) | SIFT tolerated (0.31); PolyPhen benign (0.034); catalogued as rs767249856, COSV100642418, COSV61425518; called by muse, mutect2, varscan2
- APC | c.781A>G p.N261D | Missense Mutation (SNP) | VAF 13/36 reads (36%) | SIFT tolerated (0.43); PolyPhen benign (0.003); catalogued as COSV99965769; called by muse, mutect2, varscan2
- APOH | c.679A>C p.K227Q | Missense Mutation (SNP) | VAF 8/109 reads (7%) | SIFT tolerated (0.18); PolyPhen benign (0.003); catalogued as COSV99235589; called by muse, mutect2
- ARFGEF1 | c.3293G>C p.G1098A | Missense Mutation (SNP) | VAF 11/72 reads (15%) | SIFT tolerated (0.76); PolyPhen benign (0.025); catalogued as COSV99141211; called by muse, mutect2, varscan2
- ARHGEF7 | c.1556G>A p.G519D (on ENST00000375741 / NM_001113511.2; = p.G341D on NM_003899.5 and 5 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 11/46 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99521079; called by muse, mutect2, varscan2
- ARSK | c.380G>C p.G127A | Missense Mutation (SNP) | VAF 6/21 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV101187516; called by muse, mutect2, varscan2
- ATF7IP | c.961G>C p.G321R | Missense Mutation (SNP) | VAF 4/22 reads (18%) | SIFT tolerated, low confidence (0.46); PolyPhen benign (0); catalogued as COSV99661254; called by muse, mutect2
- ATP8B3 | c.2540A>T p.D847V | Missense Mutation (SNP) | VAF 14/62 reads (23%) | SIFT tolerated (0.06); PolyPhen benign (0.14); catalogued as rs1019255215, COSV100034103; called by muse, mutect2, varscan2
- B4GALNT3 | c.286G>T p.D96Y | Missense Mutation (SNP) | VAF 27/120 reads (23%) | SIFT deleterious (0.01); PolyPhen benign (0.259); catalogued as COSV99842567; called by muse, mutect2, varscan2
- BRINP2 | c.1928A>T p.H643L | Missense Mutation (SNP) | VAF 5/36 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV100837875; called by muse, mutect2, varscan2
- CADPS | c.3026+2T>C p.X1009_splice | Splice Site (SNP) | VAF 26/137 reads (19%) | catalogued as COSV99336274; called by muse, mutect2, varscan2
- CCDC141 | c.2753A>G p.K918R | Missense Mutation (SNP) | VAF 5/19 reads (26%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV99836256; called by muse, mutect2, varscan2
- CHD5 | c.5629C>T p.R1877W | Missense Mutation (SNP) | VAF 26/160 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs947205115, COSV99312671; called by muse, mutect2, varscan2
- CHN1 | c.1003G>T p.D335Y | Missense Mutation (SNP) | VAF 7/74 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55036066, COSV99788962; called by muse, mutect2
- CLPB | c.792C>G p.F264L | Missense Mutation (SNP) | VAF 12/154 reads (8%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.998); catalogued as COSV99577680; called by muse, mutect2
- CLTCL1 | c.716G>T p.G239V | Missense Mutation (SNP) | VAF 14/167 reads (8%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV99594582; called by muse, mutect2
- CMAS | c.766A>G p.I256V | Missense Mutation (SNP) | VAF 12/77 reads (16%) | SIFT tolerated (0.43); PolyPhen benign (0.01); catalogued as rs151143902; called by muse, mutect2, varscan2
- CNTNAP5 | c.2902C>A p.H968N | Missense Mutation (SNP) | VAF 22/81 reads (27%) | SIFT deleterious (0.04); PolyPhen benign (0.05); catalogued as COSV101443129; called by muse, mutect2, varscan2
- COL22A1 | c.2464-2A>T p.X822_splice | Splice Site (SNP) | VAF 12/47 reads (26%) | catalogued as COSV100276667; called by muse, mutect2, varscan2
- CPLX3 | c.443T>A p.L148H | Missense Mutation (SNP) | VAF 34/76 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100547586; called by muse, varscan2
- CRAT | c.25G>T p.V9L | Missense Mutation (SNP) | VAF 4/30 reads (13%) | SIFT tolerated (0.62); PolyPhen benign (0); catalogued as COSV100533949; called by muse, mutect2
- CROT | c.994G>T p.A332S | Missense Mutation (SNP) | VAF 5/32 reads (16%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.535); catalogued as COSV100519366; called by muse, mutect2, varscan2
- CSF1 | c.272A>G p.D91G | Missense Mutation (SNP) | VAF 18/229 reads (8%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.665); catalogued as COSV100294334; called by muse, mutect2
- CSRNP3 | c.761C>A p.A254E | Missense Mutation (SNP) | VAF 5/58 reads (9%) | SIFT tolerated (0.27); PolyPhen possibly damaging (0.708); catalogued as COSV100085225; called by muse, mutect2
- CYP4F11 | c.316A>G p.I106V | Missense Mutation (SNP) | VAF 69/332 reads (21%) | SIFT tolerated (0.11); PolyPhen benign (0); catalogued as rs566368344, COSV99930658; called by muse, mutect2, varscan2
- DCAF13 | c.916A>G p.I306V | Missense Mutation (SNP) | VAF 10/64 reads (16%) | SIFT tolerated (0.61); PolyPhen benign (0.047); catalogued as rs1453180772, COSV99885065; called by muse, mutect2, varscan2
- DDX43 | c.1045G>A p.V349I | Missense Mutation (SNP) | VAF 6/24 reads (25%) | SIFT tolerated (1); PolyPhen benign (0.051); catalogued as COSV100946242; called by muse, mutect2, varscan2
- DLX1 | c.230G>T p.S77I | Missense Mutation (SNP) | VAF 85/314 reads (27%) | SIFT tolerated (0.14); PolyPhen benign (0.067); catalogued as COSV100249829; called by muse, mutect2, varscan2
- DNAH9 | c.1682G>T p.R561M | Missense Mutation (SNP) | VAF 17/60 reads (28%) | SIFT tolerated (0.08); PolyPhen benign (0.015); catalogued as COSV52343214; called by muse, mutect2, varscan2
- DNAH9 | c.1683G>T p.R561S | Missense Mutation (SNP) | VAF 17/61 reads (28%) | SIFT tolerated (0.59); PolyPhen benign (0.007); catalogued as COSV99304470; called by muse, mutect2, varscan2
- DPYD | c.2785C>G p.L929V | Missense Mutation (SNP) | VAF 16/93 reads (17%) | SIFT tolerated (0.2); PolyPhen benign (0.044); catalogued as COSV100928760; called by muse, mutect2, varscan2
- DUSP5 | c.700C>G p.H234D | Missense Mutation (SNP) | VAF 22/306 reads (7%) | SIFT deleterious (0); PolyPhen benign (0.422); catalogued as COSV100851835; called by muse, mutect2
- EEA1 | c.1798G>A p.D600N | Missense Mutation (SNP) | VAF 10/153 reads (7%) | SIFT deleterious (0.03); PolyPhen benign (0.156); catalogued as COSV100467024, COSV100467178; called by muse, mutect2
- EMX2 | c.495G>T p.Q165H | Missense Mutation (SNP) | VAF 10/74 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV101463580; called by muse, mutect2, varscan2
- EPHA10 | c.1561C>T p.P521S | Missense Mutation (SNP) | VAF 52/260 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV100361065; called by muse, mutect2, varscan2
- EXOC5 | c.2065C>T p.H689Y | Missense Mutation (SNP) | VAF 9/259 reads (3%) | SIFT tolerated (1); PolyPhen possibly damaging (0.828); catalogued as rs1056656432, COSV100566985; called by muse, mutect2
- FAF1 | c.352G>C p.D118H | Missense Mutation (SNP) | VAF 6/37 reads (16%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.879); catalogued as COSV100875361; called by muse, mutect2, varscan2
- FAM135B | c.1885G>T p.V629L | Missense Mutation (SNP) | VAF 9/63 reads (14%) | SIFT tolerated (0.87); PolyPhen benign (0); catalogued as rs542927659, COSV99419896; called by muse, mutect2, varscan2
- FAM135B | c.1884G>T p.M628I | Missense Mutation (SNP) | VAF 8/62 reads (13%) | SIFT tolerated (0.19); PolyPhen benign (0.003); catalogued as COSV99419909; called by muse, mutect2, varscan2
- FAP | c.1693G>T p.E565* | Nonsense Mutation (SNP) | VAF 8/45 reads (18%) | catalogued as COSV99501796; called by muse, mutect2, varscan2
- FBXL5 | c.1483G>A p.E495K | Missense Mutation (SNP) | VAF 11/54 reads (20%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.197); catalogued as COSV100377691; called by muse, mutect2, varscan2
- FHL5 | c.118T>C p.Y40H | Missense Mutation (SNP) | VAF 19/89 reads (21%) | SIFT tolerated (0.19); PolyPhen benign (0.03); catalogued as COSV100459190; called by muse, mutect2, varscan2
- FN1 | c.6757G>C p.D2253H (on ENST00000359671 / NM_001365524.2; = p.D2222H on NM_002026.4) | Missense Mutation (SNP) | VAF 7/39 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100116320; called by muse, mutect2, varscan2
- FOXP2 | c.97G>C p.D33H | Missense Mutation (SNP) | VAF 5/84 reads (6%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.984); catalogued as COSV63490002; called by muse, mutect2
- GJA8 | c.280G>T p.G94W | Missense Mutation (SNP) | VAF 11/212 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53788916, COSV99569142; called by muse, mutect2
- GPRASP1 | c.2010G>C p.E670D | Missense Mutation (SNP) | VAF 11/51 reads (22%) | SIFT tolerated (0.45); PolyPhen benign (0.003); catalogued as COSV100850921; called by muse, mutect2, varscan2
- HMCN1 | c.9374C>T p.T3125I | Missense Mutation (SNP) | VAF 5/44 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV99624986, COSV99637270; called by muse, mutect2
- IFT172 | c.3992A>G p.N1331S | Missense Mutation (SNP) | VAF 5/68 reads (7%) | SIFT tolerated (0.34); PolyPhen benign (0); catalogued as COSV99561916; called by muse, mutect2
- IGLL5 | c.431G>A p.G144E | Missense Mutation (SNP) | VAF 9/81 reads (11%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.899); catalogued as COSV101138642; called by muse, mutect2, varscan2
- IL1RAPL1 | c.1528A>G p.I510V | Missense Mutation (SNP) | VAF 9/28 reads (32%) | SIFT tolerated (0.7); PolyPhen benign (0.22); catalogued as COSV100145489; called by muse, mutect2, varscan2
- INSC | c.834G>T p.K278N | Missense Mutation (SNP) | VAF 19/96 reads (20%) | SIFT deleterious (0); PolyPhen benign (0.281); catalogued as rs1223548598, COSV101088817; called by muse, mutect2, varscan2
- ITGBL1 | c.1481C>T p.P494L | Missense Mutation (SNP) | VAF 38/101 reads (38%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.17); catalogued as rs1224041765, COSV101084925; called by muse, varscan2
- KCND3 | c.1149C>A p.F383L | Missense Mutation (SNP) | VAF 4/42 reads (10%) | SIFT tolerated (0.23); PolyPhen benign (0.048); catalogued as COSV100136867, COSV56176973; called by mutect2, varscan2
- KIF4B | c.1904A>T p.K635M | Missense Mutation (SNP) | VAF 11/54 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.928); catalogued as COSV101469203; called by muse, mutect2, varscan2
- KRT6A | c.1038G>T p.Q346H | Missense Mutation (SNP) | VAF 61/343 reads (18%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.944); catalogued as COSV100416753; called by muse, mutect2, varscan2
- KRTAP4-4 | c.299G>T p.C100F | Missense Mutation (SNP) | VAF 105/306 reads (34%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.958); catalogued as COSV101180534; called by muse, mutect2, varscan2
- LRRC4C | c.251A>G p.H84R | Missense Mutation (SNP) | VAF 12/93 reads (13%) | SIFT tolerated (0.38); PolyPhen benign (0.04); catalogued as COSV99537171; called by muse, mutect2, varscan2
- MAGEA11 | c.989C>A p.P330H | Missense Mutation (SNP) | VAF 43/114 reads (38%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.566); catalogued as COSV100290402; called by muse, mutect2, varscan2
- MEGF8 | c.7859G>A p.G2620E (on ENST00000251268 / NM_001271938.2; = p.G2553E on NM_001410.3) | Missense Mutation (SNP) | VAF 20/142 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV99234722; called by muse, mutect2, varscan2
- MEI1 | c.3104C>A p.S1035Y | Missense Mutation (SNP) | VAF 5/38 reads (13%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.823); catalogued as COSV100299668; called by muse, mutect2, varscan2
- MUC16 | c.26295C>G p.I8765M | Missense Mutation (SNP) | VAF 9/79 reads (11%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.087); catalogued as COSV101197898, COSV101198420; called by muse, mutect2, varscan2
- MYH7 | c.5065C>T p.R1689C | Missense Mutation (SNP) | VAF 44/208 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs730880915, COSV62522904; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- MYO3A | c.572G>T p.W191L | Missense Mutation (SNP) | VAF 12/110 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1165683221, COSV99778583; called by muse, mutect2, varscan2
- NAA25 | c.2183G>A p.R728H | Missense Mutation (SNP) | VAF 8/84 reads (10%) | SIFT tolerated (0.09); PolyPhen benign (0); catalogued as rs116838734, COSV55701991; called by mutect2, varscan2
- NCKAP1L | c.893T>A p.V298E | Missense Mutation (SNP) | VAF 10/74 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.601); catalogued as COSV99514544, COSV99514579; called by muse, mutect2, varscan2
- NETO1 | c.606C>A p.C202* | Nonsense Mutation (SNP) | VAF 33/139 reads (24%) | catalogued as COSV100198297; called by muse, mutect2, varscan2
- NEURL4 | c.3895G>T p.A1299S | Missense Mutation (SNP) | VAF 53/204 reads (26%) | SIFT tolerated (0.74); PolyPhen benign (0.01); catalogued as COSV100222701, COSV100222735; called by muse, mutect2, varscan2
- NRG3 | c.532A>T p.S178C | Missense Mutation (SNP) | VAF 12/200 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); catalogued as COSV64567851; called by muse, mutect2
- NRG3 | c.1759C>A p.L587M (on ENST00000404547 / NM_001370084.1; = p.L563M on NM_001010848.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 12/191 reads (6%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.075); catalogued as COSV100930828; called by muse, mutect2
- NSMAF | c.1527G>T p.W509C | Missense Mutation (SNP) | VAF 28/125 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99232417, COSV99232438; called by muse, mutect2, varscan2
- OR4Q3 | c.283C>A p.L95I | Missense Mutation (SNP) | VAF 5/71 reads (7%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.675); catalogued as COSV100056758; called by muse, mutect2
- OR4Q3 | c.596T>A p.M199K | Missense Mutation (SNP) | VAF 17/110 reads (15%) | SIFT deleterious (0.03); PolyPhen benign (0.211); catalogued as COSV100056762; called by muse, mutect2, varscan2
- OR4Q3 | c.597G>C p.M199I | Missense Mutation (SNP) | VAF 17/110 reads (15%) | SIFT tolerated (0.08); PolyPhen benign (0.007); catalogued as COSV100056763, COSV59179945; called by muse, mutect2, varscan2
- OR5L1 | c.644T>A p.L215H | Missense Mutation (SNP) | VAF 11/110 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV61735172; called by muse, mutect2, varscan2
- OR5T1 | c.646G>T p.G216C | Missense Mutation (SNP) | VAF 27/110 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.736); catalogued as rs748261639, COSV57303984; called by muse, mutect2, varscan2
- OR8A1 | c.838G>T p.V280L | Missense Mutation (SNP) | VAF 5/48 reads (10%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.35); catalogued as COSV99420356; called by muse, mutect2, varscan2
- PATJ | c.2236G>C p.D746H | Missense Mutation (SNP) | VAF 10/100 reads (10%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.88); catalogued as COSV100333307; called by muse, mutect2
- PBRM1 | c.814-2A>G p.X272_splice | Splice Site (SNP) | VAF 4/14 reads (29%) | catalogued as rs1161522910, COSV56261313; called by mutect2, varscan2
- PCDH7 | c.1924G>T p.D642Y | Missense Mutation (SNP) | VAF 14/54 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.781); catalogued as COSV100687640; called by muse, mutect2, varscan2
- PCDH9 | c.3286C>T p.Q1096* (on ENST00000377865 / NM_203487.3; = p.Q1062* on NM_020403.5 and 1 other RefSeq transcript) | Nonsense Mutation (SNP) | VAF 21/93 reads (23%) | catalogued as COSV100118772; called by muse, mutect2, varscan2
- PCLO | c.10999G>T p.A3667S | Missense Mutation (SNP) | VAF 22/158 reads (14%) | SIFT tolerated (0.87); PolyPhen benign (0.048); catalogued as COSV100428097; called by muse, mutect2, varscan2
- PIK3CG | c.949G>A p.E317K | Missense Mutation (SNP) | VAF 21/132 reads (16%) | SIFT tolerated (0.75); PolyPhen benign (0.053); catalogued as rs759136884, COSV63248027; called by muse, mutect2, varscan2
- PLCB2 | c.1097C>A p.P366H | Missense Mutation (SNP) | VAF 30/106 reads (28%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.448); catalogued as COSV99541640; called by muse, mutect2, varscan2
- PLCH1 | c.3170G>T p.G1057V (on ENST00000340059 / NM_001130960.2; = p.G1049V on NM_014996.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 17/107 reads (16%) | SIFT tolerated, low confidence (0.19); PolyPhen benign (0.058); catalogued as rs1363289785, COSV100395791, COSV58193851; called by muse, mutect2, varscan2
- PLEKHA5 | c.533A>T p.K178I | Missense Mutation (SNP) | VAF 5/32 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100163651; called by muse, mutect2, varscan2
- PLXNA1 | c.5334G>C p.Q1778H | Missense Mutation (SNP) | VAF 14/192 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99302432; called by muse, mutect2
- PNKD | c.985T>G p.C329G | Missense Mutation (SNP) | VAF 70/368 reads (19%) | SIFT tolerated (0.07); PolyPhen benign (0.217); catalogued as COSV99282200; called by muse, mutect2, varscan2
- PPIL2 | c.1064G>T p.R355L | Missense Mutation (SNP) | VAF 1463/1707 reads (86%) | SIFT tolerated (0.07); PolyPhen benign (0.079); catalogued as COSV100622453; called by muse, mutect2, varscan2
- PPP6R2 | c.1100G>A p.R367Q | Missense Mutation (SNP) | VAF 12/72 reads (17%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.994); catalogued as rs765476879, COSV53292319; called by muse, mutect2, varscan2
- PSMD5 | c.808C>G p.L270V | Missense Mutation (SNP) | VAF 5/32 reads (16%) | SIFT deleterious (0.01); PolyPhen benign (0.264); catalogued as rs1469780149, COSV99270663; called by muse, mutect2, varscan2
- RAB33B | c.615A>C p.L205F | Missense Mutation (SNP) | VAF 6/51 reads (12%) | SIFT deleterious (0.04); PolyPhen benign (0.202); catalogued as COSV99978137; called by muse, mutect2, varscan2
- RAB4A | c.194A>T p.Q65L | Missense Mutation (SNP) | VAF 8/34 reads (24%) | SIFT deleterious (0.03); PolyPhen benign (0.001); catalogued as COSV100797036; called by muse, mutect2, varscan2
- RAD21 | c.1517C>T p.P506L | Missense Mutation (SNP) | VAF 10/106 reads (9%) | SIFT deleterious (0); PolyPhen benign (0.081); catalogued as rs781356173, COSV52064608; called by muse, mutect2
- RBM11 | c.473A>G p.Y158C | Missense Mutation (SNP) | VAF 22/126 reads (17%) | SIFT tolerated (0.14); PolyPhen benign (0.003); catalogued as COSV101271184; called by muse, mutect2, varscan2
- REG3G | c.242G>T p.S81I | Missense Mutation (SNP) | VAF 13/185 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.901); catalogued as COSV99709256; called by muse, mutect2
- RGS2 | c.14T>A p.M5K | Missense Mutation (SNP) | VAF 25/104 reads (24%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.227); catalogued as COSV99343288; called by muse, mutect2, varscan2
- RXYLT1 | c.1180G>T p.A394S | Missense Mutation (SNP) | VAF 6/36 reads (17%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.945); catalogued as COSV99706738; called by muse, mutect2, varscan2
- SCN5A | c.2637G>C p.W879C | Missense Mutation (SNP) | VAF 29/197 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as COSV100346779; called by muse, mutect2, varscan2
- SERPINA4 | c.1261G>T p.V421F | Missense Mutation (SNP) | VAF 12/68 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV100096987; called by muse, mutect2, varscan2
- SERPINB12 | c.1076C>A p.A359E | Missense Mutation (SNP) | VAF 13/73 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99501510; called by muse, mutect2, varscan2
- SLAMF6 | c.89T>A p.V30E | Missense Mutation (SNP) | VAF 17/151 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV100924837; called by muse, mutect2, varscan2
- SLC9A2 | c.1035G>T p.K345N | Missense Mutation (SNP) | VAF 19/76 reads (25%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.761); catalogued as COSV99295915; called by muse, mutect2, varscan2
- SSH1 | c.1537C>T p.R513* | Nonsense Mutation (SNP) | VAF 12/168 reads (7%) | catalogued as rs765866095, COSV100425360; called by muse, mutect2
- STOML3 | c.769G>T p.A257S | Missense Mutation (SNP) | VAF 6/70 reads (9%) | SIFT tolerated (0.82); PolyPhen benign (0.086); catalogued as rs1447788415, COSV65512109; called by muse, mutect2
- STRC | c.3773G>A p.S1258N | Missense Mutation (SNP) | VAF 20/74 reads (27%) | SIFT tolerated (0.17); PolyPhen benign (0.009); catalogued as COSV101372190; called by mutect2, varscan2
- STXBP3 | c.1019A>G p.Q340R | Missense Mutation (SNP) | VAF 6/90 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.6); catalogued as COSV100893897; called by muse, mutect2
- SYNE1 | c.6773T>C p.V2258A (on ENST00000367255 / NM_182961.4; = p.V2265A on NM_033071.3) | Missense Mutation (SNP) | VAF 7/53 reads (13%) | SIFT deleterious (0); PolyPhen benign (0.054); catalogued as COSV99555253; called by muse, mutect2, varscan2
- SYT12 | c.266G>A p.R89Q | Missense Mutation (SNP) | VAF 37/311 reads (12%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0); catalogued as rs200281326, COSV67354607; called by muse, mutect2, varscan2
- TANC2 | c.1072T>C p.S358P | Missense Mutation (SNP) | VAF 9/70 reads (13%) | SIFT tolerated (0.38); PolyPhen benign (0); catalogued as COSV101267262; called by muse, mutect2, varscan2
- TAOK1 | c.1792G>A p.E598K | Missense Mutation (SNP) | VAF 35/105 reads (33%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); catalogued as COSV99913600; called by muse, mutect2, varscan2
- TFCP2L1 | c.1341+2T>G p.X447_splice | Splice Site (SNP) | VAF 57/162 reads (35%) | catalogued as COSV99747824; called by muse, mutect2, varscan2
- THSD7A | c.674C>A p.P225Q | Missense Mutation (SNP) | VAF 7/42 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV101448566; called by muse, mutect2, varscan2
- TRIM61 | c.140T>C p.L47P | Missense Mutation (SNP) | VAF 9/69 reads (13%) | SIFT deleterious (0); PolyPhen benign (0.261); catalogued as COSV100255939; called by muse, mutect2, varscan2
- TRIO | c.946G>C p.D316H | Missense Mutation (SNP) | VAF 14/175 reads (8%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.674); catalogued as COSV100709987; called by muse, mutect2
- TRIO | c.3133G>A p.D1045N | Missense Mutation (SNP) | VAF 14/222 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV100709988; called by muse, mutect2
- UACA | c.4232G>A p.R1411Q | Missense Mutation (SNP) | VAF 13/50 reads (26%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.895); catalogued as rs773466932, COSV100537306; called by muse, mutect2, varscan2
- USP22 | c.437C>T p.S146L | Missense Mutation (SNP) | VAF 11/102 reads (11%) | SIFT tolerated (0.68); PolyPhen benign (0); catalogued as COSV99820100; called by muse, mutect2, varscan2
- USP34 | c.2146C>T p.Q716* | Nonsense Mutation (SNP) | VAF 12/168 reads (7%) | catalogued as COSV101276738; called by muse, mutect2
- ZFC3H1 | c.3749G>C p.G1250A | Missense Mutation (SNP) | VAF 4/52 reads (8%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.997); catalogued as COSV101110360; called by muse, mutect2
- COLQ | c.233_249del p.D78Afs*50 | Frame Shift Del (DEL) | VAF 17/93 reads (18%) | called by mutect2, pindel
- CRYBG2 | c.682T>A p.S228T | Missense Mutation (SNP) | VAF 13/73 reads (18%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.771); called by muse, mutect2, varscan2
- FOXC2 | c.1308del p.G437Afs*35 | Frame Shift Del (DEL) | VAF 18/97 reads (19%) | called by mutect2, pindel, varscan2
- HIVEP1 | c.1615del p.E539Kfs*3 | Frame Shift Del (DEL) | VAF 14/39 reads (36%) | called by mutect2, pindel, varscan2
- HTT | c.273del p.E91Dfs*10 | Frame Shift Del (DEL) | VAF 6/27 reads (22%) | called by mutect2, pindel, varscan2
- OR2T4 | c.5A>C p.D2A | Missense Mutation (SNP) | VAF 9/55 reads (16%) | PolyPhen benign (0); called by muse, mutect2, varscan2
- TRHDE | c.2376del p.W794Gfs*25 | Frame Shift Del (DEL) | VAF 8/49 reads (16%) | called by mutect2, pindel
- ADCYAP1R1 | c.363T>C p.D121= | Silent (SNP) | VAF 24/132 reads (18%) | catalogued as COSV100416247; called by muse, mutect2, varscan2
- ASAP1 | c.3063A>G p.S1021= | Silent (SNP) | VAF 34/174 reads (20%) | catalogued as COSV100726890; called by muse, mutect2, varscan2
- BIRC6 | c.6111G>T p.L2037= | Silent (SNP) | VAF 7/24 reads (29%) | catalogued as COSV101427942; called by muse, mutect2, varscan2
- C5orf51 | c.711T>C p.T237= | Silent (SNP) | VAF 25/77 reads (32%) | catalogued as COSV101068876; called by muse, mutect2, varscan2
- CCM2 | c.105G>A p.K35= | Silent (SNP) | VAF 6/69 reads (9%) | catalogued as COSV99347556; called by muse, mutect2
- CDHR2 | c.492G>A p.E164= | Silent (SNP) | VAF 12/52 reads (23%) | catalogued as COSV99991124; called by muse, mutect2, varscan2
- CYP2F1 | c.237C>T p.S79= | Silent (SNP) | VAF 12/113 reads (11%) | catalogued as rs763356097, COSV100462568; called by muse, mutect2, varscan2
- FBXW11 | c.1560A>G p.L520= | Silent (SNP) | VAF 17/73 reads (23%) | catalogued as COSV99439883; called by muse, mutect2, varscan2
- FMN2 | c.3456C>A p.P1152= | Silent (SNP) | VAF 39/182 reads (21%) | catalogued as COSV100143270, COSV60446839; called by muse, mutect2, varscan2
- GJA8 | c.279G>A p.V93= | Silent (SNP) | VAF 10/212 reads (5%) | catalogued as rs1357719204, COSV99569140; called by muse, mutect2
- GREM1 | c.339C>A p.I113= | Silent (SNP) | VAF 14/69 reads (20%) | catalogued as COSV100277805; called by muse, mutect2, varscan2
- HSD3B2 | c.60C>T p.R20= | Silent (SNP) | VAF 8/69 reads (12%) | catalogued as COSV101027427; called by mutect2, varscan2
- IPO13 | c.2700G>T p.L900= | Silent (SNP) | VAF 29/152 reads (19%) | catalogued as COSV99664280; called by muse, mutect2, varscan2
- IRF3 | c.618G>A p.V206= | Silent (SNP) | VAF 23/248 reads (9%) | catalogued as COSV99880907; called by muse, mutect2
- LRP1B | c.1182G>T p.V394= | Silent (SNP) | VAF 11/131 reads (8%) | catalogued as COSV101253541; called by muse, mutect2
- MAL | c.330C>G p.T110= | Silent (SNP) | VAF 96/263 reads (37%) | catalogued as COSV100015645; called by muse, mutect2, varscan2
- MICAL2 | c.621A>T p.T207= | Silent (SNP) | VAF 33/185 reads (18%) | catalogued as COSV99816814; called by muse, mutect2, varscan2
- MROH2B | c.2619G>A p.L873= | Silent (SNP) | VAF 8/101 reads (8%) | catalogued as COSV101270475; called by muse, mutect2
- MXRA5 | c.6015C>T p.H2005= | Silent (SNP) | VAF 10/31 reads (32%) | catalogued as rs758500843, COSV54235580; called by muse, mutect2, varscan2
- NCKAP5 | c.3480C>T p.L1160= | Silent (SNP) | VAF 10/78 reads (13%) | catalogued as COSV100490381; called by muse, varscan2
- NDUFB5 | c.54G>C p.L18= | Silent (SNP) | VAF 9/55 reads (16%) | catalogued as rs1201463103, COSV99372462; called by muse, mutect2, varscan2
- OR4D10 | c.744C>G p.T248= | Silent (SNP) | VAF 48/339 reads (14%) | catalogued as COSV101596996; called by muse, mutect2, varscan2
- OR8I2 | c.708C>A p.A236= | Silent (SNP) | VAF 27/120 reads (23%) | catalogued as COSV100135880; called by muse, mutect2, varscan2
- OR8K3 | c.297A>G p.T99= | Silent (SNP) | VAF 7/37 reads (19%) | catalogued as COSV100449683; called by muse, mutect2, varscan2
- PALM | c.756G>T p.G252= | Silent (SNP) | VAF 11/61 reads (18%) | catalogued as COSV99214330; called by muse, mutect2, varscan2
- PKHD1L1 | c.3585G>A p.V1195= | Silent (SNP) | VAF 6/25 reads (24%) | catalogued as COSV101005529; called by muse, mutect2, varscan2
- RNF19A | c.1803G>C p.L601= | Silent (SNP) | VAF 5/71 reads (7%) | catalogued as COSV100347429; called by muse, mutect2
- SCN2A | c.5694C>A p.T1898= | Silent (SNP) | VAF 3/25 reads (12%) | catalogued as COSV99330349; called by muse, mutect2
- SLC22A2 | c.1338C>A p.A446= | Silent (SNP) | VAF 44/137 reads (32%) | catalogued as COSV100870936; called by muse, mutect2, varscan2
- SLC22A3 | c.120C>A p.V40= | Silent (SNP) | VAF 10/31 reads (32%) | catalogued as COSV99278421; called by muse, mutect2, varscan2
- SOX6 | c.912C>G p.P304= | Silent (SNP) | VAF 16/80 reads (20%) | catalogued as rs772358464, COSV100323421, COSV57035743; called by muse, mutect2, varscan2
- TRIM14 | c.852C>G p.A284= | Silent (SNP) | VAF 5/34 reads (15%) | catalogued as rs777800386, COSV99271058; called by muse, mutect2, varscan2
- TRIM48 | c.69A>G p.Q23= | Silent (SNP) | VAF 20/210 reads (10%) | catalogued as COSV101338206; called by muse, mutect2
- UBIAD1 | c.357G>A p.R119= | Silent (SNP) | VAF 8/83 reads (10%) | catalogued as COSV100954808; called by muse, mutect2, varscan2
- WRAP73 | c.150G>A p.Q50= | Silent (SNP) | VAF 12/60 reads (20%) | catalogued as COSV99573146; called by muse, mutect2, varscan2
- ZFYVE16 | c.4566T>C p.S1522= | Silent (SNP) | VAF 16/35 reads (46%) | catalogued as rs1246604680, COSV100566236; called by muse, mutect2, varscan2
- ZNF264 | c.1425C>T p.S475= | Silent (SNP) | VAF 4/70 reads (6%) | catalogued as COSV99567125; called by muse, mutect2
